Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3532, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3532-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Resectate of the colon under inclusion of a moderately differentiated adenocarcinoma of the colorectal type, of maximum 2.5 cm in size, with infiltration of the pericolic fatty tissue. Tumor-free regional lymph nodes. Tumor-free mesenteric resection margin. Tumor-free large intestinal resection margins.

Tumor stage: pT3 pN0 (0/35) pMX; G2, L0, V0, locally R0

Source: NCI Genomic Data Commons file 4f9c1cb4-5a80-4b3a-b01d-4ffa3851f168 (TCGA-AA-3532.82516932-0618-4E40-9B7F-BCC09639E261.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).